Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A4KN, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A4KN-01A (Primary Tumor).

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1. LYMPH NODES ANTERIOR TO TRACHEA (RESECTION): THREE (3) LYMPH NODES, NEGATIVE FOR TUMOR.

2. THYROID (THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

TUMOR SITE:

Right lobe

HISTOLOGIC TYPE:

Papillary carcinoma with focal tall cell features

TUMOR SIZE:

2.0 cm

FOCALITY:

Unifocal

LYMPH NODES:

All 4 lymph nodes are negative for tumor

EXTENT OF INVASION (7th Edition AJCC):

PRIMARY TUMOR:

pT3: Tumor with minimal extrathyroidal extension

REGIONAL LYMPH NODES:

pNO: No regional lymph node metastasis

MARGINS:

Margins are uninvolved

Distance of invasive carcinoma from nearest margin: <1 mm (anterior margin)

VENOUS/LYMPHATIC INVASION:

Absent

3. THYMIC LYMPH NODE: ONE LYMPH NODE, NEGATIVE FOR TUMOR.

100-0-3
carcinoma, papillary, tall cell 8344/3
Site: thyroid, nos c73.4
pw
10/3/12

> 50% tall cell per BS.
pw

pw
10/3/12

Source: NCI Genomic Data Commons file 753aa21a-ab01-4ff4-8db6-b61d91a383fe (TCGA-ET-A4KN.440686B6-A7D3-4817-9CBB-2C0CEA3C440D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).